Somatic mutation profile of tumor specimen TCGA-UF-A7JK-01A (aliquot TCGA-UF-A7JK-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JK, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.4 years (21,696 days).
Specimen TCGA-UF-A7JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09cd15a0-e5a6-418e-a883-2fce441d4587.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JK-10A (Blood Derived Normal), aliquot TCGA-UF-A7JK-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4429323-9b29-4bf1-9af7-fc25cebd1b5b

The open-access MAF lists 125 somatic variants for this specimen: 86 protein-altering or splice-affecting, 37 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 37, Nonsense Mutation 8, Splice Site 3, Splice Region 2, Intron 1, RNA 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.604_618del p.R202_L206del | In Frame Del (DEL) | VAF 31/53 reads (58%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ACOX3 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 63/364 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100711846; called by muse, varscan2
- ADGRV1 | c.15541G>C p.E5181Q | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV101315607; called by muse, mutect2, varscan2
- ADIPOR1 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1393878346, COSV100579436; called by muse, mutect2, varscan2
- AFF2 | c.2629A>G p.I877V | Missense Mutation (SNP) | VAF 160/198 reads (81%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99662515; called by muse, mutect2, varscan2
- AL592490.1 | c.1727C>A p.P576H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.852); catalogued as COSV101308127; called by muse, mutect2, varscan2
- ASTN1 | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.953); catalogued as COSV99920796; called by muse, mutect2, varscan2
- BMPR2 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as rs368430622; called by muse, mutect2, varscan2
- BRCA2 | c.4156G>A p.D1386N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555283600, COSV101204007, COSV66462217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C7 | c.1646A>T p.E549V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100495538; called by muse, mutect2, varscan2
- CACNA1C | c.4783C>T p.R1595W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs867596743, COSV100216598; called by muse, mutect2
- CAPZA3 | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.3); catalogued as COSV99855980; called by muse, mutect2, varscan2
- CCDC7 | c.2585C>A p.S862Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.985); catalogued as rs1284535700, COSV100177725; called by muse, mutect2, varscan2
- CD2 | c.252T>A p.Y84* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV101040111; called by muse, mutect2, varscan2
- CDK5RAP1 | c.746C>A p.S249Y | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100211934; called by muse, mutect2, varscan2
- CPNE9 | c.544A>G p.T182A | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV99808107; called by muse, mutect2, varscan2
- CROCC | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as rs757760286, COSV100978096; called by muse, mutect2, varscan2
- CYP3A43 | c.1254-2A>G p.X418_splice (on ENST00000354829 / NM_057095.3; = p.R419G on NM_022820.5) | Splice Site (SNP) | VAF 24/73 reads (33%) | catalogued as COSV99733014; called by muse, mutect2, varscan2
- DCST1 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757073967, COSV99664796; called by muse, mutect2, varscan2
- DDX28 | c.899T>A p.V300E | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100192916; called by muse, mutect2, varscan2
- EDN1 | c.546G>A p.M182I | Missense Mutation (SNP) | VAF 129/247 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65080791; called by muse, mutect2, varscan2
- FAM107B | c.260G>A p.R87Q (on ENST00000378458 / NM_001320737.1; = p.R262Q on NM_031453.3) | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs1421681819, COSV99473634; called by muse, mutect2, varscan2
- FERMT1 | c.1424A>G p.K475R | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.179); catalogued as COSV99451218; called by muse, mutect2, varscan2
- FGB | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV57419704; called by muse, mutect2, varscan2
- FXYD5 | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs1451396257, COSV100732595; called by muse, mutect2, varscan2
- GABRB3 | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs144496462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBF1 | c.1191G>T p.L397F (on ENST00000369983 / NM_001377137.1; = p.L396F on NM_004193.3) | Missense Mutation (SNP) | VAF 118/497 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as rs1046955179, COSV100890366; called by muse, mutect2, varscan2
- GPR148 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV99998533; called by muse, mutect2, varscan2
- GRIN3B | c.1115G>T p.S372I | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99312276; called by muse, mutect2
- GRM7 | c.1975C>T p.R659* | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | catalogued as rs1390058794, COSV63143649, COSV63161230; called by muse, mutect2, varscan2
- HOXA13 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763515; called by muse, mutect2, varscan2
- HSPH1 | c.2098A>T p.T700S | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV100184717; called by muse, mutect2, varscan2
- IL4R | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 30/94 reads (32%) | catalogued as COSV99404728, COSV99404845; called by muse, mutect2, varscan2
- JAG2 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1416221890, COSV100077991; called by muse, mutect2, varscan2
- KCNH1 | c.1105G>A p.D369N (on ENST00000271751 / NM_172362.3; = p.D342N on NM_002238.4) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657904; called by muse, mutect2, varscan2
- KIF9 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV99646461; called by muse, mutect2, varscan2
- KRI1 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs375673634; called by muse, mutect2, varscan2
- LCP2 | c.826G>T p.G276W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50457655, COSV99252280; called by muse, mutect2, varscan2
- LRATD2 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100513542; called by muse, mutect2, varscan2
- LRP2 | c.6374G>A p.R2125H | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.997); catalogued as rs752202886, COSV55568391; called by muse, mutect2, varscan2
- MAGI2 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833549; called by muse, mutect2, varscan2
- MAGI2 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833550; called by muse, mutect2, varscan2
- MAPK7 | c.677G>A p.W226* | Nonsense Mutation (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100218813; called by muse, mutect2, varscan2
- MFSD4A | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs545692163, COSV65656576; called by muse, mutect2, varscan2
- MMP12 | c.1073T>G p.L358* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100404849; called by muse, mutect2, varscan2
- MPIG6B | c.370G>C p.G124R | Missense Mutation (SNP) | VAF 23/186 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as COSV101008055; called by muse, mutect2, varscan2
- MYH1 | c.3488C>A p.A1163D | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99875192; called by muse, mutect2, varscan2
- MYH13 | c.1681A>G p.K561E | Missense Mutation (SNP) | VAF 129/182 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99352804; called by muse, mutect2, varscan2
- MYLK | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as rs201265306, COSV60612429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN1 | c.1817G>T p.W606L | Missense Mutation (SNP) | VAF 44/179 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848873; called by muse, mutect2, varscan2
- PANK2 | c.1471A>T p.R491* (on ENST00000316562 / NM_153638.3; = p.R200* on NM_024960.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 42/129 reads (33%) | catalogued as COSV100262171; called by muse, mutect2, varscan2
- PATZ1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.613); catalogued as rs377660548; called by muse, mutect2, varscan2
- PCDHA10 | c.1193C>A p.S398Y | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100248584; called by muse, mutect2, varscan2
- PKHD1 | c.3364+2T>G p.X1122_splice | Splice Site (SNP) | VAF 46/196 reads (23%) | catalogued as COSV100581739; called by muse, mutect2, varscan2
- PKP2 | c.1475C>G p.T492R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99297371; called by muse, mutect2, varscan2
- POM121L12 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 424/484 reads (88%) | catalogued as COSV101374872; called by muse, mutect2, varscan2
- PROC | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99300697; called by muse, mutect2, varscan2
- REV3L | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV100725011; called by muse, mutect2, varscan2
- RRAD | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.984); catalogued as COSV100233716; called by muse, mutect2, varscan2
- SELENBP1 | c.1133T>C p.V378A | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs781185794, COSV100923614; called by muse, mutect2, varscan2
- SEMA4G | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99272088; called by muse, mutect2, varscan2
- SH3D19 | c.1276A>G p.I426V | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1014636565, COSV100455547; called by muse, mutect2, varscan2
- SH3PXD2A | c.2176G>A p.A726T (on ENST00000369774 / NM_001365079.1; = p.A698T on NM_014631.2) | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.267); catalogued as rs371681573; called by muse, mutect2, varscan2
- SLC24A4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs748090494, COSV100104560; called by muse, mutect2, varscan2
- SLC32A1 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99461921; called by muse, mutect2
- SLC6A3 | c.940G>C p.A314P | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54361185; called by muse, mutect2
- SLC8A3 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs369662157; called by muse, mutect2, varscan2
- SLC9A4 | c.2021G>T p.R674M | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as rs773038353, COSV99762794; called by muse, mutect2, varscan2
- SPINT4 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as rs769960383, COSV99650962; called by muse, mutect2, varscan2
- ST6GAL2 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | PolyPhen benign (0.2); catalogued as rs751305558, COSV64528573; called by muse, mutect2, varscan2
- STYXL2 | c.2807A>T p.N936I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99608754; called by muse, mutect2, varscan2
- TBC1D8 | c.2886T>A p.D962E | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.752); catalogued as COSV99961401; called by muse, mutect2, varscan2
- TCF3 | c.1324C>T p.L442= | Splice Region (SNP) | VAF 5/9 reads (56%) | catalogued as rs553896459, COSV99513716; called by muse, varscan2
- TMEM50B | c.97T>C p.L33= | Splice Region (SNP) | VAF 29/91 reads (32%) | catalogued as COSV101336635; called by muse, mutect2, varscan2
- TRPC4AP | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs893100286, COSV52677477, COSV99328745; called by muse, mutect2, varscan2
- TSGA10 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751796811, COSV61825697; called by muse, mutect2, varscan2
- TTC25 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101102892, COSV66367483; called by muse, mutect2, varscan2
- TTN | c.55129G>A p.E18377K (on ENST00000591111; = p.E10953K on NM_003319.4) | Missense Mutation (SNP) | VAF 52/104 reads (50%) | PolyPhen benign (0.355); catalogued as COSV100599807; called by muse, mutect2, varscan2
- TUB | c.1222G>A p.E408K (on ENST00000299506 / NM_177972.3; = p.E463K on NM_003320.4) | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100210078; called by muse, mutect2, varscan2
- UHRF1BP1 | c.915C>A p.S305R | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.107); catalogued as COSV99511582; called by muse, mutect2, varscan2
- USP9Y | c.235A>T p.M79L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.136); catalogued as COSV100168240; called by muse, mutect2, varscan2
- XXYLT1 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV100118168; called by muse, mutect2, varscan2
- ZIC2 | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891767; called by muse, mutect2, varscan2
- ZIC3 | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 93/122 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99798545; called by muse, mutect2, varscan2
- ANK3 | c.2267_2283+25del p.X756_splice | Splice Site (DEL) | VAF 8/70 reads (11%) | called by mutect2, pindel
- HMGB3 | c.536dup p.V180Gfs*6 | Frame Shift Ins (INS) | VAF 44/80 reads (55%) | called by mutect2, pindel, varscan2
- ADAM10 | c.2211C>T p.P737= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV99545702; called by muse, mutect2, varscan2
- APOB | c.1458T>C p.Y486= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as rs1349207899, COSV99264272; called by muse, mutect2, varscan2
- BEND7 | c.870G>A p.R290= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV100346464; called by muse, mutect2, varscan2
- CASKIN2 | c.2298G>A p.P766= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs772294520, COSV100050199; called by muse, mutect2, varscan2
- CATSPERD | c.1923C>T p.P641= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58466101; called by muse, mutect2, varscan2
- CCDC33 | c.39G>A p.E13= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as COSV100350814; called by muse, mutect2, varscan2
- CCDC82 | c.459A>G p.L153= | Silent (SNP) | VAF 38/206 reads (18%) | catalogued as rs1276712939, COSV99567127; called by muse, varscan2
- CCHCR1 | c.921G>A p.L307= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100885587; called by muse, mutect2, varscan2
- CHRDL1 | c.618T>C p.D206= (on ENST00000372045; = p.D212= on NM_145234.4) | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99487813; called by muse, mutect2, varscan2
- CLK2 | c.1200C>T p.I400= (on ENST00000368361 / NM_001294339.2; = p.I399= on NM_003993.4) | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100226615; called by muse, mutect2, varscan2
- COLGALT2 | c.426C>G p.A142= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV100730482; called by muse, mutect2, varscan2
- CYLC1 | c.1200A>C p.A400= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100254250; called by muse, mutect2
- DCAF11 | c.1464C>T p.D488= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as rs771919028, COSV100386609; called by muse, mutect2, varscan2
- DNAJC13 | c.1668G>A p.L556= | Silent (SNP) | VAF 66/214 reads (31%) | catalogued as COSV53448874; called by muse, mutect2, varscan2
- EPHA10 | c.2430G>A p.A810= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs780958682, COSV57624881; called by muse, mutect2, varscan2
- FNBP1 | c.1704G>A p.T568= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs781328311, COSV63088976; called by muse, mutect2, varscan2
- FOXR2 | c.630C>T p.H210= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV59258633, COSV99080878; called by muse, mutect2, varscan2
- FSD2 | c.741T>C p.N247= | Silent (SNP) | VAF 111/163 reads (68%) | catalogued as COSV100575053; called by muse, mutect2, varscan2
- GREB1 | c.1080A>T p.P360= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV99302389; called by muse, mutect2, varscan2
- GRM3 | c.2625C>G p.T875= | Silent (SNP) | VAF 39/134 reads (29%) | catalogued as COSV100862233; called by muse, mutect2, varscan2
- HEATR3 | c.366T>C p.D122= | Silent (SNP) | VAF 54/261 reads (21%) | catalogued as COSV99589802; called by muse, mutect2, varscan2
- KAT2A | c.517C>T p.L173= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV99863433; called by muse, mutect2, varscan2
- MLEC | c.174G>T p.A58= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs745594964, COSV99949589; called by muse, mutect2, varscan2
- MYH1 | c.5142T>C p.S1714= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99875189; called by muse, mutect2
- NCLN | c.1608C>T p.L536= | Silent (SNP) | VAF 57/172 reads (33%) | catalogued as rs780930005, COSV55743172; called by muse, mutect2, varscan2
- PLEKHN1 | c.834G>A p.S278= (on ENST00000379409; = p.S226= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs375169656; called by muse, varscan2
- PLXNC1 | c.3387G>A p.T1129= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as rs767708332, COSV99312611; called by muse, mutect2, varscan2
- PPARGC1A | c.1542C>T p.S514= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as rs529792659, COSV53528699; called by muse, mutect2, varscan2
- PRAMEF2 | c.663A>T p.I221= | Silent (SNP) | VAF 57/285 reads (20%) | catalogued as COSV99534976; called by muse, mutect2, varscan2
- PSMD14 | c.489C>A p.I163= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV101293926, COSV68832055; called by muse, mutect2, varscan2
- PYGM | c.1350G>A p.S450= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs1399322723, COSV51217274; called by muse, mutect2
- RHCG | c.921C>A p.L307= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1015099065, COSV99174078; called by muse, mutect2, varscan2
- ST6GAL2 | c.1269G>A p.E423= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV100699538, COSV62416365; called by muse, mutect2, varscan2
- SYT6 | c.984T>C p.I328= (on ENST00000610222 / NM_001366225.1; = p.I243= on NM_205848.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV101059619; called by muse, mutect2, varscan2
- TPP2 | c.15G>A p.A5= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101060202; called by muse, mutect2, varscan2
- WNT3 | c.1047C>T p.Y349= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as rs571188215, COSV56647526; called by muse, mutect2, varscan2
- ZNF835 | c.690G>A p.A230= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1462215301, COSV73379370; called by muse, mutect2, varscan2
- CASP10 | c.1415+8067A>T | Intron (SNP) | VAF 21/117 reads (18%) | catalogued as COSV99628827; called by muse, mutect2, varscan2
- UBTFL2 | n.252G>C | RNA (SNP) | VAF 15/84 reads (18%) | called by muse, mutect2, varscan2
